MMRF case MMRF_2265 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/51cfbd41-2e79-474c-9e74-0ae13d8924fe

Demographics
Sex at birth: female; Race: other; Ethnicity: hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.3 years (24,594 days); ISS stage: I; Days to last known disease status: 876 days (2.4 years); Days to last follow up: 876 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 124 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 153 days; Days to treatment end: 153 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 158 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 159 days; Days to treatment end: 159 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days; Days to treatment end: 315 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 4.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 288 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.608 mg/dL; Immunoglobulin G 7.16 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.96 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 343 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.48 mmol/L; Albumin 41.7 g/L; Total Protein 7.1 g/dL; Glucose 5.4 mmol/L; C-Reactive Protein 1.46 mg/dL.
- Day 77 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.233 mg/dL; Immunoglobulin G 4.75 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 5 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 52 µmol/L; Calcium 2.29 mmol/L; Albumin 38.8 g/L; Total Protein 6.2 g/dL; Glucose 5.1 mmol/L.
- Day 153 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 5.22 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 356 ×10⁹/L; Creatinine 56 µmol/L; Calcium 2.19 mmol/L; Albumin 30 g/L; Total Protein 6.4 g/dL; Glucose 6.8 mmol/L.
- Day 260 (ECOG 1): M Protein 4.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 8.57 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 322 ×10⁹/L; Creatinine 60 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.41 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 6.2 mmol/L.
- Day 343 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 6.63 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 55 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.24 mmol/L; Albumin 43.2 g/L; Total Protein 6.7 g/dL; Glucose 4.7 mmol/L.
- Day 428 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 9.85 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 55 µmol/L; Blood Urea Nitrogen 4.4 mmol/L; Calcium 2.26 mmol/L; Albumin 44.2 g/L; Total Protein 7.3 g/dL; Glucose 5.5 mmol/L.
- Day 512 (ECOG 2): M Protein 5.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 384 ×10⁹/L; Creatinine 59 µmol/L; Blood Urea Nitrogen 6 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 7.6 mmol/L.
- Day 596 (ECOG 1): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 333 ×10⁹/L; Creatinine 57 µmol/L; Blood Urea Nitrogen 3.6 mmol/L; Calcium 2.26 mmol/L; Albumin 41.8 g/L; Total Protein 7.3 g/dL.
- Day 680 (ECOG 1): M Protein 6.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 1.99 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 63 µmol/L; Blood Urea Nitrogen 4.4 mmol/L; Calcium 2.36 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 6.2 mmol/L.
- Day 792 (ECOG 1): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 64 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 5.4 mmol/L.
- Day 876 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 59 µmol/L; Blood Urea Nitrogen 5.2 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 5.4 mmol/L.

Other clinical attributes
- Day -13: Weight: 76 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2265_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_2265_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
